Somatic mutation profile of tumor specimen TCGA-AR-A2LM-01A (aliquot TCGA-AR-A2LM-01A-11D-A17W-09) from TCGA case TCGA-AR-A2LM, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 49.4 years (18,053 days).
Specimen TCGA-AR-A2LM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef383034-1e77-4dc9-9283-357f7cb1549e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AR-A2LM-10A (Blood Derived Normal), aliquot TCGA-AR-A2LM-10A-01D-A17W-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/05d84381-e080-4387-afe9-74a007a4dd37

The open-access MAF lists 16 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 3, Frame Shift Ins 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1035T>A p.N345K | Missense Mutation (SNP) | VAF 10/43 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs121913284, COSV55873276; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CATSPERE | c.1826C>A p.T609N | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.142); catalogued as COSV63677835; called by muse, mutect2, varscan2
- ESF1 | c.1213C>G p.L405V | Missense Mutation (SNP) | VAF 46/216 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52520832; called by muse, mutect2, varscan2
- KCNIP1 | c.136C>T p.R46W (on ENST00000411494 / NM_001034837.3; = p.R35W on NM_014592.4) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV61080140; called by muse, mutect2, varscan2
- SLC30A1 | c.907G>C p.A303P | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.691); catalogued as COSV65361011; called by muse, mutect2, varscan2
- SORCS3 | c.1786G>A p.D596N | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs142652556; called by muse, mutect2, varscan2
- TCERG1L | c.1016C>G p.P339R | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV64050014; called by muse, mutect2, varscan2
- TENT5D | c.409G>T p.V137F | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as COSV57636603; called by muse, mutect2, varscan2
- USP48 | c.2732A>G p.N911S | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.024); catalogued as rs778692028, COSV57609837; called by muse, mutect2, varscan2
- ZBTB32 | c.107G>A p.G36E | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.28); catalogued as rs267605433, COSV52890535; called by muse, mutect2, varscan2
- CDH1 | c.421_439dup p.P147Hfs*27 | Frame Shift Ins (INS) | VAF 12/44 reads (27%) | called by mutect2, varscan2
- NRIP1 | c.713dup p.R239Kfs*14 | Frame Shift Ins (INS) | VAF 37/179 reads (21%) | called by mutect2, pindel, varscan2
- PCDHAC2 | c.675G>T p.L225= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV99145718; called by muse, mutect2
- PREX2 | c.3825C>T p.V1275= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as COSV55769168; called by muse, mutect2, varscan2
- RPRD1A | c.15T>C p.S5= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as rs779588997, COSV59822027; called by muse, mutect2, varscan2
- KRT18P23 | chr22:44571466 G>A | 3'Flank (SNP) | VAF 31/105 reads (30%) | catalogued as rs1328277541; called by muse, mutect2, varscan2
